Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QS, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QS-01A (Primary Tumor).

[page 1 of 2]
ICD 0-3
Thymoma, type B2, malignant 8584/3
Site: Thymus C37.9
QJ 4/2/14

Nature of sampling : thymectomy

Macroscopic examination :

1 . thymectomy :

Thymectomy specimen weighs 75 g fresh and addressed oriented . It measures 10 cm x 7.5 cm x 4 cm . It is bordered by a strip of lung parenchyma measuring 5 x 1.5 cm and a tab pericardium at the posterior surface measuring 6 x 4 cm . The limits of resection are marked with green ink .

When cut , the presence of a whitish nodule, ill-defined , non-encapsulated macroscopically, and invading the pulmonary parenchyma and the pericardium and the adjacent adipose tissue .

This nodule measuring 7 cm x 4 cm x 4 cm.

2 . Left pleural nodule 0.8 x 1 cm, whitish cut.

3 . Implant of the left pleura :

Five biopsy fragments of 0.7 to 3 cm of seat whitish nodules of 0.5 to 1.5 cm diameter .

4 . Diaphragmatic implant :

The tongue of the diaphragm measuring 5 x 3 cm . It is home to three nodules individual measuring 0.6 to 2 cm in major axis , although limited , in the cutting whitish .

5 . Mediastinal fat : Two fragments respectively measuring 4 x 2.5 cm and 6.5 x 4.5 cm . No individualisable nodule on storied samples taken .

Histopathological examination :

1 . Thymectomy (1A -1E)

When cut , the tumor is lobulated , separated by septa . Tumor cells are large , polygonal , with large nuclei , prominent nucleolus. They are arranged in bays or fences around the vascular structures and septa . Lymphocyte quota is relatively abundant disseminated without lymphoid follicle individualized .

[page 2 of 2]
Few areas of peripheral medullary differentiation. Absence of Hassall's corpuscle .
The tumor is poorly defined and invades the mediastinal fat.
The limits of surgical resection are in healthy tissue.
- The adjacent parenchyma thymic nodule (1F) comprises a thymus involution
fat persistently rare lobulated structures.

Immunohistochemical examination :

- Epithelial Cells :

Expression of cytokeratin KL1 , 5/6 and 19 .

Lack of expression of cytokeratin 20 , the CD5 and CD20 . few homes EMA +

- T Lymphocyte phenotype , immature : CD5 + , CD1a + , CD99 + .

2 . Left pleural nodule :

Pleural nodule consists exclusively by type B2 thymoma .

3 . Implant at the left pleura :

All nodules examined show the same histological appearance identical . Thymoma
B2 .

4 . Diaphragmatic implant : The diaphragm is the seat of a nodule matching
Histologically B2 thymoma described above.

5 . Mediastinal fat : lobule of adipose tissue without lymph node structure
and / or normal or thymic tumor parenchyma .

Conclusion :

Thymoma subtype B2 7 cm .

Excision in full.

Stage IVa . Masaoka revised classification

Source: NCI Genomic Data Commons file 5a211de0-7f91-43dd-a1b7-28eaa1b9622d (TCGA-4V-A9QS.54CD5E0C-790C-47CF-A9BF-F63476FEA6B2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).